TCGA case TCGA-95-8039 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - Emory. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/87f1b3df-4bc7-4336-b658-f30ac1c5c796

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Acinar cell carcinoma (the primary disease): ICD-O-3 morphology code: 8550/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.1 years (26,317 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Acinar cell carcinoma). Age at diagnosis: 72.7 years (26,545 days); Days to diagnosis: 228 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Days to follow up: 27 days; Disease response: Tumor Free.
- Day 228 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 228 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 830 days (2.3 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 98; FEV1/FVC after bronchodilator (%): 70; FEV1/FVC before bronchodilator (%): 67; FEV1 after bronchodilator (% of reference): 2.54; FEV1 before bronchodilator (% of reference): 2.4.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-95-8039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-95-8039-01A-01-TS1: Section location: Top; Percent tumor nuclei: 70; Percent necrosis: 3.
- Sample TCGA-95-8039-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-95-8039-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Acinar Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Upper; Pulmonary function test indicator: Yes; Fev1 percent ref prebroncholiator: 2.40; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Complete Remission/Response; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 2, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 830 days; disease-specific survival: no event (censored), 830 days; disease-free interval: event (new tumor event after initially disease-free), 228 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 228 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-95-8039-01A-11D-2237-01): tumor purity 0.47, ploidy 1.93, whole-genome doublings 0.
